Somatic mutation profile of tumor specimen TCGA-W7-A93N-01A (aliquot TCGA-W7-A93N-01A-11D-A46P-09) from TCGA case TCGA-W7-A93N, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen TCGA-W7-A93N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a167037f-1334-42b9-973b-9b17066fff08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W7-A93N-11A (Solid Tissue Normal), aliquot TCGA-W7-A93N-11A-11D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e887e862-3fd7-4bfa-8189-ba418c00b592

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPAP1 | c.2735G>T p.S912I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV100274814; called by muse, mutect2
- ABCA4 | c.2244C>A p.C748* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- LDOC1 | c.402C>A p.D134E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2
- NETO2 | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2
- TMCO4 | c.1255C>A p.Q419K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.099); called by muse, mutect2, varscan2
